Somatic mutation profile of tumor specimen TCGA-CG-5733-01A (aliquot TCGA-CG-5733-01A-11D-1600-08) from TCGA case TCGA-CG-5733, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 83.9 years (30,650 days).
Specimen TCGA-CG-5733-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df82d3b0-5372-4184-8a75-fb13b73242d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5733-11A (Solid Tissue Normal), aliquot TCGA-CG-5733-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf703c9-1f91-4d39-a914-0b4aa0137390

The open-access MAF lists 1,306 somatic variants for this specimen: 999 protein-altering or splice-affecting, 278 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 633, Silent 278, Frame Shift Del 251, Frame Shift Ins 47, Nonsense Mutation 24, Splice Site 20, Intron 13, In Frame Del 12, Splice Region 8, 3'UTR 6, 3'Flank 4, RNA 4.

Variants (750 of 1,306; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.1290del p.F430Lfs*25 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs387906578, CD065661; ClinVar: pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 52/190 reads (27%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.5073del p.K1691Nfs*15 | Frame Shift Del (DEL) | VAF 35/135 reads (26%) | catalogued as rs80359479; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- COL1A2 | c.2845G>A p.G949S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72659312, CM940299, COSV51957440, COSV51960999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP27B1 | c.171dup p.L58Afs*275 | Frame Shift Ins (INS) | VAF 32/124 reads (26%) | catalogued as rs763437121; ClinVar: pathogenic; called by mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 106/428 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GAA | c.2242del p.E748Rfs*16 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | catalogued as rs777275355, CM082763, CM128388, CM970554; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1940dup p.P648Tfs*2 | Frame Shift Ins (INS) | VAF 14/55 reads (25%) | catalogued as rs770315135; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LBR | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777172, CM109413, COSV55288547, COSV99687557; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 26/124 reads (21%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- MYH7 | c.5134C>T p.R1712W | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913650, CM050714, COSV62521173; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PANK2 | c.1441C>T p.R481* (on ENST00000316562 / NM_153638.3; = p.R190* on NM_024960.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/99 reads (30%) | catalogued as rs137852968, CM023193, COSV57255385; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 30/110 reads (27%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 52/188 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 63/250 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- SDHA | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs9809219, CM951146, COSV53770788; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 42/160 reads (26%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.7735del p.I2579* | Frame Shift Del (DEL) | VAF 114/266 reads (43%) | catalogued as COSV71288654; called by mutect2, varscan2
- ABCB1 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.385); catalogued as COSV55956002, COSV55958048; called by muse, mutect2, varscan2
- ABCB6 | c.1606T>C p.Y536H | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54697776; called by muse, mutect2, varscan2
- ABCC11 | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 40/117 reads (34%) | catalogued as rs752713916, COSV62324355; called by muse, mutect2, varscan2
- ABCC3 | c.3164C>T p.S1055L | Missense Mutation (SNP) | VAF 123/375 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1220211975, COSV53325102, COSV99558815; called by muse, mutect2, varscan2
- ABCF2 | c.1210A>G p.K404E | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV55184424; called by muse, mutect2, varscan2
- ACAD8 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756612574, COSV55541290; called by muse, mutect2, varscan2
- ACCSL | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.206); catalogued as rs371463744; called by muse, mutect2, varscan2
- ACO1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 13/323 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1036093594, COSV59379264; called by muse, mutect2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 57/217 reads (26%) | catalogued as COSV57774850; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 123/236 reads (52%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM11 | c.104del p.G35Afs*52 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | catalogued as rs767694891; called by mutect2, pindel, varscan2
- ADAM22 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55982522; called by muse, mutect2, varscan2
- ADAMTS16 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751536987, COSV56996986; called by muse, mutect2, varscan2
- ADAMTS18 | c.2013A>C p.K671N | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1447392490, COSV51417223, COSV51418778; called by muse, mutect2, varscan2
- ADAMTS8 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs1417726772, COSV57294935; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1771A>G p.N591D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52819364; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRF2 | c.1957G>A p.A653T (on ENST00000296862 / NM_001368115.2; = p.A585T on NM_153839.7) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771938865, COSV57287952; called by muse, mutect2, varscan2
- ADGRL3 | c.3243G>A p.W1081* (on ENST00000506720 / NM_001322402.2; = p.W1013* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 55/264 reads (21%) | catalogued as COSV72231169; called by muse, mutect2, varscan2
- AGBL2 | c.2309T>G p.M770R | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54093627; called by muse, mutect2, varscan2
- AHI1 | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV55630950; called by muse, mutect2
- AHNAK | c.17470A>G p.T5824A | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV57220726; called by muse, mutect2, varscan2
- AHRR | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1237683475, COSV57086994, COSV57092035; called by muse, mutect2, varscan2
- AKAP8L | c.634A>G p.M212V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV68473923; called by muse, mutect2, varscan2
- ALDH1B1 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV66620203; called by muse, mutect2, varscan2
- ALDH4A1 | c.1567del p.A523Pfs*71 (on ENST00000290597 / NM_170726.3; = p.A523Pfs*122 on NM_003748.4) | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs754334877; called by mutect2, varscan2
- ALKBH4 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769756616, COSV52961368; called by muse, mutect2
- AMER2 | c.1616G>C p.S539T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV63438675; called by muse, mutect2, varscan2
- ANKRD24 | c.2009C>T p.T670I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV53672804; called by muse, mutect2
- ANKRD49 | c.258+13del | Splice Region (DEL) | VAF 48/112 reads (43%) | catalogued as rs750258320; called by mutect2, varscan2
- APLP2 | c.2222A>G p.H741R | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53842091; called by muse, mutect2, varscan2
- APOL3 | c.1037G>A p.G346D (on ENST00000349314 / NM_145640.2; = p.G275D on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62580229; called by muse, mutect2, varscan2
- AQP7 | c.408G>A p.T136= | Splice Region (SNP) | VAF 18/104 reads (17%) | catalogued as rs528904601, COSV53023480; called by muse, mutect2, varscan2
- AR | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV65959678, COSV65960660; called by muse, mutect2, varscan2
- ARAP2 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV58288999; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARID2 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as rs1374682629, COSV57608879; called by muse, mutect2, varscan2
- ARID2 | c.652del p.S218Pfs*74 | Frame Shift Del (DEL) | VAF 39/162 reads (24%) | catalogued as rs1433103583; called by mutect2, pindel, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 60/204 reads (29%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as rs753865255; called by mutect2, varscan2
- ASAH1 | c.349T>A p.L117M | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV50502913; called by muse, mutect2, varscan2
- ASAP1 | c.1652G>T p.R551M | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV63051387; called by muse, mutect2
- ASAP2 | c.2506G>A p.V836M | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.654); catalogued as rs745984762, COSV55634538; called by muse, mutect2, varscan2
- ASPSCR1 | c.1186C>A p.L396M | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.713); catalogued as COSV60729853; called by muse, mutect2, varscan2
- ATG101 | c.545T>C p.L182S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV61085419; called by muse, mutect2, varscan2
- ATP11C | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs1042049467, COSV59568314; called by muse, mutect2, varscan2
- ATP13A4 | c.2720T>C p.M907T | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV61322424; called by muse, mutect2
- ATP1A1 | c.121A>G p.M41V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1384870128, COSV55192531; called by muse, mutect2, varscan2
- ATP1A4 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769122428, COSV100927426, COSV63627195; called by muse, mutect2, varscan2
- ATP2B2 | c.1645G>A p.A549T (on ENST00000352432; = p.A515T on NM_001683.5) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as rs761133287, COSV100660041; called by muse, mutect2, varscan2
- ATP6V0D1 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV52098898; called by muse, mutect2, varscan2
- ATP9B | c.1304A>G p.Y435C | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1435975413, COSV56955382; called by muse, mutect2
- ATPSCKMT | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV54727204; called by muse, mutect2, varscan2
- ATXN2 | c.3247G>A p.A1083T (on ENST00000550104; = p.A923T on NM_002973.4) | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs759657946, COSV66481411; called by muse, mutect2, varscan2
- B3GALT2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.777); catalogued as COSV66464303, COSV66464417; called by muse, mutect2, varscan2
- B9D2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.255); catalogued as rs761158280, COSV54684382; called by muse, mutect2, varscan2
- BEND3 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as rs1434744523, COSV64681571; called by muse, mutect2, varscan2
- BICD2 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63549850; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs776003776; called by mutect2, varscan2
- BNIP5 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV71325696; called by muse, mutect2, varscan2
- BOLL | c.656A>G p.Q219R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV56575503; called by muse, mutect2, varscan2
- BOLL | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56575515; called by muse, mutect2, varscan2
- BORCS5 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV53803534; called by muse, mutect2, varscan2
- BRCA2 | c.1043T>C p.V348A | Missense Mutation (SNP) | VAF 144/461 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.117); catalogued as COSV66448250; called by muse, mutect2, varscan2
- BRD8 | c.1227A>C p.E409D (on ENST00000254900 / NM_139199.2; = p.E482D on NM_006696.4) | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.349); catalogued as COSV50156454; called by muse, mutect2, varscan2
- BSN | c.7841C>T p.T2614M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751028351, COSV56522332; called by muse, mutect2, varscan2
- BTN1A1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55068533; called by muse, mutect2, varscan2
- C10orf71 | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.187); catalogued as COSV60509882; called by muse, mutect2, varscan2
- C2orf69 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs767688764, COSV60666206, COSV60667094; called by muse, mutect2
- C8orf34 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs759948704, COSV100445184, COSV61386335; called by muse, mutect2, varscan2
- CAAP1 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 34/595 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV61701116; called by muse, mutect2
- CACNA1E | c.3473G>A p.C1158Y | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV62387130; called by muse, mutect2, varscan2
- CAMK2G | c.1520C>T p.A507V (on ENST00000423381 / NM_001367518.1; = p.A444V on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55216138; called by muse, mutect2, varscan2
- CAPNS2 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs778611244, COSV50896939; called by muse, mutect2, varscan2
- CASP5 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV52829854; called by muse, varscan2
- CASS4 | c.2210G>A p.S737N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV64387294; called by muse, mutect2, varscan2
- CBL | c.1484del p.P495Rfs*120 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | catalogued as COSV99081295; called by mutect2, pindel, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 51/273 reads (19%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC180 | c.1595G>T p.S532I | Missense Mutation (SNP) | VAF 90/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63832182; called by muse, mutect2, varscan2
- CCDC27 | c.1971G>T p.*657Yext*34 | Nonstop Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV53901601; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 48/149 reads (32%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC57 | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as COSV66438311; called by muse, mutect2, varscan2
- CCDC7 | c.3805G>A p.V1269I | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); catalogued as rs202101331; called by muse, mutect2, varscan2
- CCDC74A | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54608027; called by muse, mutect2, varscan2
- CCDC88C | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs754028369, COSV66232440; called by muse, mutect2, varscan2
- CCDC96 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 136/471 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs931430734, COSV59508667; called by muse, mutect2, varscan2
- CCDC97 | c.47-1G>T p.X16_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV54190951; called by muse, mutect2, varscan2
- CCNE1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52904985; called by muse, mutect2, varscan2
- CCNL1 | c.1109A>G p.Q370R | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.316); catalogued as COSV55819833; called by muse, mutect2
- CD7 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV53939972; called by muse, mutect2, varscan2
- CD70 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV55566554; called by muse, mutect2, varscan2
- CD74 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1195416511, COSV50533404; called by muse, mutect2, varscan2
- CD86 | c.935G>A p.R312H (on ENST00000330540 / NM_175862.5; = p.R306H on NM_006889.4) | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs370380261; called by muse, mutect2, varscan2
- CDH13 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV51841883; called by muse, mutect2, varscan2
- CDH2 | c.1491del p.F497Lfs*20 | Frame Shift Del (DEL) | VAF 33/153 reads (22%) | catalogued as COSV99297181; called by mutect2, pindel, varscan2
- CDH8 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54856365; called by muse, mutect2
- CDH9 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV50272370, COSV50332333; called by muse, mutect2, varscan2
- CDHR5 | c.1641dup p.G548Rfs*161 (on ENST00000358353 / NM_001171968.2; = p.G554Rfs*161 on NM_021924.5) | Frame Shift Ins (INS) | VAF 27/157 reads (17%) | catalogued as rs775160782; called by mutect2, pindel, varscan2
- CDK12 | c.2518A>G p.M840V | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV71001568; called by muse, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 40/136 reads (29%) | catalogued as rs763090473; called by mutect2, varscan2
- CELF4 | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58448942; called by muse, mutect2, varscan2
- CELSR2 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as rs762922547, COSV54775414; called by muse, varscan2
- CELSR2 | c.6188C>T p.T2063M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs753241841, COSV54775425; called by muse, mutect2, varscan2
- CENPH | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs757957352, COSV51585114; called by muse, mutect2, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 85/334 reads (25%) | catalogued as COSV100071584; called by mutect2, pindel, varscan2
- CEP135 | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV57261346; called by muse, mutect2, varscan2
- CEP192 | c.2362del p.T788Qfs*40 | Frame Shift Del (DEL) | VAF 40/137 reads (29%) | catalogued as COSV58068098; called by mutect2, pindel, varscan2
- CEP85 | c.2278_2279del p.V760Hfs*20 | Frame Shift Del (DEL) | VAF 26/148 reads (18%) | catalogued as rs772239978; called by pindel, varscan2
- CEP95 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs200075663, COSV73609489; called by muse, mutect2
- CFAP20DC | c.2025G>T p.Q675H (on ENST00000482387 / NM_001351530.2; = p.Q424H on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV55923060; called by muse, mutect2, varscan2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs763364101; called by mutect2, varscan2
- CFAP91 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 92/327 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs565776294, COSV56342427, COSV99847038; called by muse, mutect2, varscan2
- CHST2 | c.911A>G p.K304R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1427946594, COSV58886171; called by muse, mutect2, varscan2
- CHST8 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754514195, COSV52860205; called by muse, varscan2
- CLIP2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1389848158, COSV56281881; called by muse, mutect2, varscan2
- CLK1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 33/121 reads (27%) | catalogued as rs1268929686, COSV58432265; called by muse, mutect2, varscan2
- CLSTN3 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs201799321; called by muse, mutect2, varscan2
- CLTA | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs765309993, COSV54255158; called by muse, mutect2, varscan2
- CLTC | c.1814T>C p.F605S | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52249439; called by muse, mutect2, varscan2
- CNGA1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.104); catalogued as COSV62055248; called by muse, mutect2, varscan2
- CNNM3 | c.2107C>T p.R703W | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as rs769820758, COSV59709483; called by muse, mutect2, varscan2
- CNOT4 | c.2090C>A p.P697H (on ENST00000541284 / NM_001190850.1; = p.P623H on NM_013316.4) | Missense Mutation (SNP) | VAF 236/508 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV64158654; called by muse, mutect2, varscan2
- CNTN4 | c.2720A>C p.N907T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV61876003; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs374805044; called by mutect2, varscan2
- COCH | c.1581G>T p.R527S (on ENST00000216361 / NM_001347720.1; = p.R462S on NM_004086.3) | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV53551726, COSV99363670; called by muse, mutect2
- COL12A1 | c.5580G>T p.L1860F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV59400425; called by muse, mutect2, varscan2
- COL20A1 | c.3647A>G p.N1216S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV58921331; called by muse, mutect2, varscan2
- COL6A6 | c.2687A>G p.D896G | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV62030132; called by muse, mutect2, varscan2
- COMMD8 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 38/143 reads (27%) | catalogued as rs769950448, COSV67500584; called by muse, mutect2, varscan2
- COQ10B | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs186425303, COSV55836959; called by muse, mutect2, varscan2
- CPQ | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs184645863, COSV55152248; called by muse, mutect2, varscan2
- CPSF1 | c.3895C>T p.R1299W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1419729322, COSV58234453; called by muse, mutect2, varscan2
- CPTP | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1240467802, COSV59564270; called by muse, mutect2, varscan2
- CRAMP1 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.843); catalogued as rs770641600, COSV51963876; called by muse, mutect2, varscan2
- CRTAC1 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1048452043, COSV54004840; called by muse, mutect2, varscan2
- CSDE1 | c.2049T>A p.D683E (on ENST00000358528 / NM_001007553.3; = p.D652E on NM_007158.6) | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as COSV54752679; called by muse, mutect2, varscan2
- CSMD1 | c.10105del p.R3369Dfs*6 (on ENST00000520002; = p.R3368Dfs*6 on NM_033225.6) | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | catalogued as COSV59289308, COSV59338652; called by mutect2, pindel
- CSMD1 | c.8219G>A p.G2740D (on ENST00000520002; = p.G2739D on NM_033225.6) | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59347092; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 27/171 reads (16%) | catalogued as rs766438669; called by pindel, varscan2
- CTBP2 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58335598; called by muse, mutect2, varscan2
- CTIF | c.1363A>G p.M455V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1283739137, COSV56487085; called by muse, mutect2, varscan2
- CUL1 | c.1460G>A p.S487N | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV57388187; called by muse, mutect2, varscan2
- CUL9 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV52731023; called by muse, mutect2, varscan2
- CUL9 | c.5632C>T p.R1878C | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs759125679, COSV52725262, COSV99334941; called by muse, mutect2, varscan2
- CXCR5 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs1486574010, COSV52686053; called by muse, mutect2, varscan2
- CYBB | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as rs781992322, COSV101059723, COSV66085391, COSV66085499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYLC1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV61413826; called by muse, mutect2, varscan2
- CYP11A1 | c.1536G>T p.W512C | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV51433242; called by muse, mutect2, varscan2
- CYP2A13 | c.1025A>C p.K342T | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.214); catalogued as COSV57838851; called by muse, mutect2
- CYP2C19 | c.1280C>G p.P427R | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64908447; called by muse, varscan2
- DCC | c.4112-2A>G p.X1371_splice | Splice Site (SNP) | VAF 35/141 reads (25%) | catalogued as COSV71433864; called by muse, mutect2, varscan2
- DCDC2 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51239825; called by muse, mutect2, varscan2
- DCLK1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773811526, COSV55196003; called by muse, mutect2
- DDX10 | c.2545G>T p.D849Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV59436984; called by muse, mutect2
- DDX25 | c.506A>G p.Q169R | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1195235808, COSV54991410; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 53/174 reads (30%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX31 | c.2527C>T p.R843W | Missense Mutation (SNP) | VAF 106/334 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs937390295, COSV55037773; called by muse, mutect2, varscan2
- DEFB113 | c.73del p.T25Qfs*? | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | catalogued as rs758917875, COSV104398000; called by mutect2, pindel, varscan2
- DENND4B | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs764111803, COSV100339169; called by muse, mutect2, varscan2
- DEUP1 | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV53213981; called by muse, mutect2, varscan2
- DHX40 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs544885439, COSV52067056; called by muse, mutect2, varscan2
- DICER1 | c.5401G>A p.D1801N | Missense Mutation (SNP) | VAF 116/392 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58623519; called by muse, mutect2, varscan2
- DISP2 | c.2816C>A p.P939H | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51128322; called by muse, mutect2, varscan2
- DISP3 | c.3998C>T p.T1333M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771544744, COSV53831514; called by muse, mutect2, varscan2
- DLD | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52738737; called by muse, mutect2
- DMRTC2 | c.819C>A p.A273= | Splice Region (SNP) | VAF 28/124 reads (23%) | catalogued as COSV54187350; called by muse, mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 41/78 reads (53%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH3 | c.7727G>A p.R2576H | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs544149586, COSV54533843; called by muse, mutect2, varscan2
- DNAH5 | c.1459T>G p.F487V | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as COSV54237708; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAH8 | c.10858C>T p.R3620W | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769053473, COSV59460786; called by muse, mutect2, varscan2
- DNAJC14 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1487047140, COSV57913574; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.3658G>A p.A1220T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV101312832; called by muse, mutect2, varscan2
- DOCK8 | c.4456C>T p.R1486C | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765335127, COSV66617530; called by muse, mutect2, varscan2
- DOP1A | c.7348del p.I2450* | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs1562402608; called by mutect2, pindel, varscan2
- DOP1B | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750339936, COSV67693181; called by muse, mutect2, varscan2
- DOP1B | c.2003C>T p.T668M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs143591918; called by muse, mutect2, varscan2
- DOT1L | c.494-1G>A p.X165_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV67111254; called by muse, mutect2, varscan2
- DRP2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65810973; called by muse, varscan2
- DSTN | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 36/154 reads (23%) | catalogued as rs1240975432, COSV55713483; called by muse, mutect2, varscan2
- DTWD1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52072151; called by muse, varscan2
- DVL3 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs760208714, COSV57457112; called by muse, mutect2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs772082432; called by mutect2, varscan2
- EEF1A2 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as COSV53207029; called by muse, mutect2, varscan2
- EFCAB5 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV57932870; called by muse, mutect2, varscan2
- EFCAB6 | c.4322G>A p.R1441H | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs915086992, COSV53061397; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 33/143 reads (23%) | catalogued as rs746692720; called by mutect2, varscan2
- EHD1 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958886354, COSV57735538; called by muse, mutect2, varscan2
- EHD3 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs780938047, COSV59029333; called by muse, mutect2, varscan2
- EHMT1 | c.3793C>T p.H1265Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.094); catalogued as COSV66044789; called by muse, mutect2, varscan2
- ELF3 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62838955, COSV62839266; called by muse, mutect2, varscan2
- ELL | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV53213915; called by muse, mutect2, varscan2
- EMC1 | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs139714938; called by muse, mutect2, varscan2
- EP400 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57777929; called by muse, mutect2, varscan2
- EPHA10 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1467024250, COSV60404453; called by muse, mutect2, varscan2
- EPHA7 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV65186890; called by muse, mutect2, varscan2
- EPHB1 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs371083718, COSV67663710, COSV67665155; called by muse, mutect2, varscan2
- EPHB1 | c.2809T>C p.F937L | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV67665162; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- ERC1 | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV61696976; called by muse, mutect2, varscan2
- ERCC6L2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs933300533, COSV56632315; called by muse, mutect2, varscan2
- ERLIN2 | c.820-1G>A p.X274_splice | Splice Site (SNP) | VAF 42/180 reads (23%) | catalogued as COSV52421268; called by muse, varscan2
- EVI5L | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54484436; called by muse, mutect2
- EXO1 | c.2190del p.D731Tfs*4 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | catalogued as rs752940417; called by pindel, varscan2
- EXT1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV65481871; called by muse, mutect2, varscan2
- EZH1 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52852128, COSV52853612; called by muse, mutect2, varscan2
- FAM111B | c.646T>G p.L216V | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as COSV59112575; called by muse, mutect2, varscan2
- FAM118A | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs34197967; called by muse, mutect2, varscan2
- FAM187B | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs559952328, COSV61201521; called by muse, mutect2, varscan2
- FAM189A2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs975013431, COSV57384310; called by muse, mutect2, varscan2
- FAM3D | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as COSV62558749; called by muse, mutect2, varscan2
- FAM47C | c.1472C>A p.P491H | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63728301; called by muse, mutect2, varscan2
- FAM83H | c.1415T>C p.L472P | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV66354156; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FARS2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs745400923, COSV51165800; called by muse, mutect2
- FBLN2 | c.1655G>T p.C552F | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55487629; called by muse, mutect2, varscan2
- FBXL22 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV62216649; called by muse, mutect2, varscan2
- FBXO11 | c.2711A>G p.E904G (on ENST00000403359 / NM_001190274.2; = p.E820G on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/345 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV52282872; called by muse, mutect2, varscan2
- FBXO24 | c.1048C>T p.P350S (on ENST00000241071 / NM_033506.3; = p.P388S on NM_012172.5) | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV53827644; called by muse, mutect2, varscan2
- FCGBP | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs782167689; called by mutect2, varscan2
- FCN1 | c.307+2T>C p.X103_splice | Splice Site (SNP) | VAF 33/124 reads (27%) | catalogued as rs749104961, COSV65662652; called by muse, mutect2, varscan2
- FCN1 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.235); catalogued as COSV65662655; called by muse, mutect2, varscan2
- FCRL3 | c.814dup p.R272Kfs*16 | Frame Shift Ins (INS) | VAF 29/126 reads (23%) | catalogued as rs1288807478; called by mutect2, varscan2
- FDPS | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.368); catalogued as rs757544890, COSV63114900; called by muse, mutect2
- FGF18 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs756441926, COSV51127441; called by muse, mutect2, varscan2
- FGF6 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs759669908, COSV57403617; called by muse, mutect2
- FHOD3 | c.2823G>T p.K941N (on ENST00000359247 / NM_001281739.3; = p.K958N on NM_025135.5) | Missense Mutation (SNP) | VAF 11/333 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57179312; called by muse, mutect2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FKBP6 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs373566157; called by muse, mutect2, varscan2
- FLAD1 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as rs145148009; called by muse, mutect2, varscan2
- FLG | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 136/475 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV64244466; called by muse, mutect2, varscan2
- FMO5 | c.829A>G p.R277G | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.17); catalogued as COSV54208397; called by muse, mutect2
- FN1 | c.6188C>A p.P2063H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV60557527; called by muse, mutect2, varscan2
- FNBP4 | c.315C>T p.G105= | Splice Region (SNP) | VAF 45/155 reads (29%) | catalogued as rs373072684; called by muse, mutect2, varscan2
- FNDC3B | c.1001+1G>A p.X334_splice | Splice Site (SNP) | VAF 45/186 reads (24%) | catalogued as rs1471911337, COSV61045461; called by muse, mutect2, varscan2
- FNDC4 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.88); PolyPhen probably damaging (1); catalogued as rs1046558, COSV53022127; called by muse, mutect2, varscan2
- FOXL2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM032239, COSV57728384; called by muse, mutect2, varscan2
- FRYL | c.1294A>G p.S432G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV51952874; called by muse, mutect2, varscan2
- FRYL | c.373T>C p.F125L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV51952885; called by muse, mutect2, varscan2
- FUT1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1194262536, COSV59569120; called by muse, mutect2, varscan2
- GAB3 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557257611, COSV65819365; called by muse, mutect2, varscan2
- GABBR1 | c.87T>C p.G29= | Splice Region (SNP) | VAF 10/118 reads (8%) | catalogued as COSV63543405, COSV63544781; called by muse, mutect2
- GABBR2 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); catalogued as rs769423854, COSV52310853; called by muse, mutect2, varscan2
- GADL1 | c.883A>G p.S295G | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56981744; called by muse, mutect2, varscan2
- GALC | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54327465; called by muse, mutect2, varscan2
- GALNT2 | c.541+2T>C p.X181_splice | Splice Site (SNP) | VAF 38/111 reads (34%) | catalogued as COSV64196138; called by muse, mutect2, varscan2
- GAREM1 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1336574428, COSV52512361; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs758551787; called by mutect2, varscan2
- GCM1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485879093, COSV52523019; called by muse, mutect2, varscan2
- GDA | c.365_367del p.E122del | In Frame Del (DEL) | VAF 79/382 reads (21%) | catalogued as rs767384214; called by pindel, varscan2
- GDPD5 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100409333; called by muse, mutect2, varscan2
- GJD2 | c.934A>G p.R312G | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.272); catalogued as COSV51749138; called by muse, mutect2
- GLI1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753380800, COSV57364352; called by muse, mutect2, varscan2
- GLS2 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs752169894, COSV57665746; called by muse, mutect2, varscan2
- GNG7 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.44); catalogued as rs566517073, COSV66286810; called by muse, mutect2, varscan2
- GORASP1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV56529757; called by muse, mutect2, varscan2
- GPATCH8 | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.915); catalogued as COSV59196032; called by muse, mutect2, varscan2
- GPR179 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs780029931; called by muse, mutect2
- GPR61 | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs767711982, COSV63984102; called by muse, mutect2, varscan2
- GPRASP1 | c.4060G>A p.V1354M | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.074); catalogued as rs751429906, COSV64356008; called by muse, mutect2, varscan2
- GPSM1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369488840; called by muse, mutect2, varscan2
- GRIK3 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV66142707; called by muse, mutect2, varscan2
- GSN | c.1344+1G>A p.X448_splice | Splice Site (SNP) | VAF 22/76 reads (29%) | catalogued as rs113048496, COSV57999055; called by muse, mutect2
- GSPT1 | c.848C>T p.P283L (on ENST00000420576 / NM_001130007.2; = p.P421L on NM_002094.4) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV70452838; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GZF1 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV57636911; called by muse, mutect2, varscan2
- H1-3 | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as rs200289213, COSV55097982; called by mutect2, varscan2
- H2AC20 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs1398776312; called by pindel, varscan2
- H2BC15 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 116/395 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV57586043; called by muse, mutect2, varscan2
- HAP1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs1555591289, COSV57879286; called by muse, mutect2, varscan2
- HAUS5 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV52548674; called by muse, mutect2, varscan2
- HCAR2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs773465504, COSV61025251; called by muse, mutect2, varscan2
- HDAC4 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs903743381, COSV100613202, COSV61869677; called by muse, mutect2, varscan2
- HEATR1 | c.6238-2A>G p.X2080_splice | Splice Site (SNP) | VAF 61/250 reads (24%) | catalogued as COSV59382104; called by muse, mutect2, varscan2
- HEATR4 | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58574571; called by muse, mutect2, varscan2
- HECTD4 | c.5356C>T p.R1786* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV66389599; called by muse, mutect2, varscan2
- HECW1 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs771147604, COSV67834314; called by muse, mutect2, varscan2
- HECW2 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV53665565; called by muse, varscan2
- HECW2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs762015382, COSV53650887; called by muse, varscan2
- HEPH | c.326A>G p.D109G (on ENST00000343002; = p.D163G on NM_138737.5) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57967247; called by muse, mutect2, varscan2
- HHIPL2 | c.130del p.Q44Sfs*48 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as COSV100596929; called by mutect2, pindel, varscan2
- HMCN1 | c.7827G>A p.W2609* | Nonsense Mutation (SNP) | VAF 81/277 reads (29%) | catalogued as COSV54916267; called by muse, mutect2, varscan2
- HOXA6 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761372561, COSV56074046; called by muse, mutect2, varscan2
- HPSE2 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs751015169, COSV65186620; called by muse, mutect2, varscan2
- HSD17B1 | c.416T>C p.L139S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56798137; called by muse, mutect2, varscan2
- HSF4 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM062776, COSV50457002; called by muse, mutect2, varscan2
- HSPB3 | c.340T>C p.F114L | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV57357183; called by muse, mutect2, varscan2
- HTRA1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM166614, COSV64564251; called by muse, mutect2, varscan2
- HYAL4 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 59/385 reads (15%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV56139328, COSV99772498; called by muse, mutect2, varscan2
- HYDIN | c.7308G>T p.Q2436H | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV59262977; called by muse, mutect2, varscan2
- HYDIN | c.3362del p.N1121Tfs*3 | Frame Shift Del (DEL) | VAF 15/152 reads (10%) | catalogued as rs764203047; called by pindel, varscan2
- IARS1 | c.3634T>C p.Y1212H | Missense Mutation (SNP) | VAF 119/418 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65116094; called by muse, mutect2, varscan2
- IBTK | c.2121dup p.G708Rfs*5 | Frame Shift Ins (INS) | VAF 48/201 reads (24%) | catalogued as rs772241425; called by mutect2, pindel, varscan2
- IBTK | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377348710; called by muse, mutect2, varscan2
- ICAM5 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV55745975; called by muse, mutect2, varscan2
- IFIT1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65661560; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGKV1-9 | c.161A>C p.Y54S | Missense Mutation (SNP) | VAF 73/298 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs370689196; called by muse, mutect2, varscan2
- IGKV1-9 | c.160T>G p.Y54D | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs566981885; called by muse, mutect2, varscan2
- IL18R1 | c.687A>G p.L229= | Splice Region (SNP) | VAF 20/83 reads (24%) | catalogued as COSV52125642; called by muse, mutect2, varscan2
- IL1B | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 54/152 reads (36%) | catalogued as rs1466522013, COSV54522225; called by muse, mutect2, varscan2
- IMMP1L | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs763006214, COSV53445280; called by muse, mutect2, varscan2
- INAVA | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs933167224, COSV66256189; called by muse, mutect2, varscan2
- INO80 | c.445_447del p.E149del | In Frame Del (DEL) | VAF 50/186 reads (27%) | catalogued as rs758372940; called by pindel, varscan2
- INPP5A | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs374027590; called by muse, mutect2, varscan2
- INTS1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67178329; called by muse, mutect2, varscan2
- IQCN | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.167); catalogued as rs746725866, COSV62748212; called by muse, mutect2, varscan2
- IRF2BP1 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56194240; called by muse, mutect2, varscan2
- IRF2BPL | c.2126A>G p.N709S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.024); catalogued as COSV53147953; called by muse, mutect2, varscan2
- IRS4 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV64534730; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | catalogued as rs762230866, COSV99339624; called by pindel, varscan2
- ITGA5 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs777360125, COSV53219246; called by muse, mutect2, varscan2
- ITGAX | c.984A>T p.Q328H | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV51648096; called by muse, mutect2, varscan2
- ITGB1BP1 | c.45A>T p.Q15H | Missense Mutation (SNP) | VAF 168/625 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53006688; called by muse, varscan2
- ITPR3 | c.5239G>A p.E1747K | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs761943200, COSV65411787; called by muse, mutect2, varscan2
- JCAD | c.3551G>A p.S1184N | Missense Mutation (SNP) | VAF 75/353 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs558409890, COSV64760605; called by muse, mutect2, varscan2
- KALRN | c.8542G>A p.A2848T (on ENST00000360013 / NM_001024660.4; = p.A1151T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52260202; called by muse, mutect2, varscan2
- KANK1 | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs146648084; called by muse, mutect2, varscan2
- KAT14 | c.1978del p.W660Gfs*35 | Frame Shift Del (DEL) | VAF 44/184 reads (24%) | catalogued as rs1370640495; called by mutect2, pindel, varscan2
- KAT6A | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.616); catalogued as rs780456616, COSV55903824; called by mutect2, varscan2
- KCNA1 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1207573200, COSV66837998, COSV66838322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 44/190 reads (23%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNG1 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as rs374287676; called by mutect2, varscan2
- KCNJ10 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194350781, COSV63634260; called by muse, mutect2, varscan2
- KCNK10 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761319967, COSV56647984; called by muse, varscan2
- KCNMA1 | c.3172A>G p.T1058A (on ENST00000286628 / NM_001161352.2; = p.T1000A on NM_002247.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV54263380; called by muse, mutect2, varscan2
- KCNMB3 | c.611del p.K204Sfs*16 | Frame Shift Del (DEL) | VAF 35/231 reads (15%) | catalogued as rs780345860; called by mutect2, pindel, varscan2
- KCTD8 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV63592005; called by muse, mutect2, varscan2
- KDM4B | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs754451824, COSV50230220; called by muse, mutect2, varscan2
- KDM6B | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs372730374; called by muse, mutect2, varscan2
- KDM6B | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.022); catalogued as rs562990964, COSV54682743; called by muse, mutect2, varscan2
- KDM8 | c.1086G>T p.Q362H | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53730134, COSV53730597; called by muse, mutect2, varscan2
- KIAA1109 | c.4770del p.K1590Nfs*11 | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | catalogued as rs779140281, COSV52689741; called by mutect2, varscan2
- KIAA1958 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233593428, COSV61725386; called by muse, mutect2, varscan2
- KIF18B | c.1382C>T p.A461V (on ENST00000593135 / NM_001265577.2; = p.A473V on NM_001264573.2) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV59274601; called by muse, mutect2, varscan2
- KIF23 | c.2417G>A p.R806H (on ENST00000260363; = p.R702H on NM_004856.7) | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs763116733, COSV52981267; called by muse, mutect2, varscan2
- KIF24 | c.1243A>G p.S415G | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV61456551; called by muse, mutect2, varscan2
- KIR3DL1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 150/515 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs1345918051, COSV100428802; called by muse, mutect2, varscan2
- KIT | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV55409768; called by muse, mutect2, varscan2
- KL | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867215187, COSV66309246; called by muse, mutect2, varscan2
- KL | c.2928del p.H977Tfs*10 | Frame Shift Del (DEL) | VAF 61/235 reads (26%) | catalogued as rs1430572004, COSV66308205; called by mutect2, pindel, varscan2
- KLC2 | c.1708del p.Q570Rfs*8 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs1183967253, COSV57581594; called by mutect2, pindel
- KLHDC2 | c.1044+1G>T p.X348_splice | Splice Site (SNP) | VAF 53/199 reads (27%) | catalogued as COSV53587784; called by muse, mutect2, varscan2
- KLHL22 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs748576405, COSV61021785; called by muse, mutect2, varscan2
- KLHL34 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as rs1464771579, COSV65279204, COSV65280308; called by muse, mutect2, varscan2
- KLHL5 | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV54676186, COSV54677550; called by muse, mutect2
- KLK1 | c.42dup p.T15Dfs*18 | Frame Shift Ins (INS) | VAF 15/51 reads (29%) | catalogued as rs758242614; called by mutect2, varscan2
- KRT15 | c.99del p.S34Vfs*31 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as COSV54178849; called by mutect2, pindel, varscan2
- KRT27 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as COSV56972471; called by muse, mutect2, varscan2
- KRT6A | c.1573G>T p.G525C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.401); catalogued as COSV58105862; called by muse, mutect2, varscan2
- LAMA5 | c.4236-1G>A p.X1412_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | catalogued as COSV53364547; called by muse, mutect2, varscan2
- LAMB1 | c.2551T>C p.C851R | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55967091; called by muse, mutect2
- LAMC2 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51457413; called by muse, mutect2, varscan2
- LAMTOR5 | c.276A>G p.*92Wext*11 (on ENST00000602318 / NM_001382293.1; = p.*174Wext*11 on NM_006402.3) | Nonstop Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as COSV56679205; called by muse, mutect2, varscan2
- LARGE1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61665750; called by muse, mutect2, varscan2
- LARP1B | c.2286G>T p.W762C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV52799681; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 47/165 reads (28%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LATS1 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.068); catalogued as COSV53594555; called by muse, mutect2, varscan2
- LCE5A | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV57500973; called by muse, mutect2, varscan2
- LGALS4 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV57044309; called by muse, mutect2, varscan2
- LILRB1 | c.1163T>C p.M388T (on ENST00000427581; = p.M352T on NM_006669.6) | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV61119683; called by muse, varscan2
- LINGO3 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as COSV68261165; called by muse, mutect2, varscan2
- LLGL1 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV57499166; called by muse, mutect2, varscan2
- LLGL1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761985510, COSV100375592, COSV57499177; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 40/170 reads (24%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMO7 | c.4991G>A p.R1664Q (on ENST00000357063; = p.R1345Q on NM_005358.5) | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.044); catalogued as rs1023410038, COSV58541484; called by muse, mutect2, varscan2
- LPAR1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs1337959313, COSV62688128; called by muse, mutect2, varscan2
- LPCAT3 | c.876A>C p.E292D | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54642632; called by muse, mutect2, varscan2
- LRFN1 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs755458726, COSV50470740; called by muse, mutect2, varscan2
- LRG1 | c.543dup p.G182Rfs*13 | Frame Shift Ins (INS) | VAF 62/267 reads (23%) | catalogued as rs34044863; called by mutect2, pindel, varscan2
- LRIT1 | c.52dup p.Q18Pfs*19 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | catalogued as rs759958964; called by mutect2, varscan2
- LRRC15 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as rs774070397, COSV61650718; called by muse, mutect2, varscan2
- LRRC2 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753497746, COSV56127349; called by muse, mutect2, varscan2
- LTBP2 | c.4982C>T p.P1661L | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV56206758, COSV56210618; called by muse, mutect2, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs754757253, COSV52588935; called by mutect2, pindel, varscan2
- LTV1 | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV52787753; called by muse, mutect2, varscan2
- LUZP1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as rs765769791, COSV56502994; called by muse, mutect2, varscan2
- LY75 | c.3299C>T p.T1100M | Missense Mutation (SNP) | VAF 19/408 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs559764685, COSV55109166; called by muse, mutect2
- LYPD1 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61417013; called by muse, mutect2, varscan2
- LZTS2 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs71488080, COSV64652218; called by muse, mutect2, varscan2
- MAGEL2 | c.3706G>A p.G1236S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs753063313, COSV58567977; called by muse, mutect2, varscan2
- MAGI3 | c.3395del p.P1132Hfs*16 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as rs1557891378; called by mutect2, pindel, varscan2
- MAMDC2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs368927463; called by muse, mutect2, varscan2
- MAMDC4 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553852620, COSV56033862; called by muse, mutect2, varscan2
- MAML1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs943494417, COSV52987082; called by muse, mutect2, varscan2
- MAP2K7 | c.447+2T>C p.X149_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV67607620, COSV67608923; called by muse, mutect2
- MAP2K7 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607626; called by muse, mutect2, varscan2
- MAP3K1 | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV68125165; called by muse, mutect2, varscan2
- MARK4 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs763202566, COSV53465896; called by muse, mutect2, varscan2
- MARVELD3 | c.948del p.Y317Tfs*45 | Frame Shift Del (DEL) | VAF 25/104 reads (24%) | catalogued as rs747980715, COSV51704302; called by mutect2, varscan2
- MAST1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52247150; called by muse, mutect2, varscan2
- MAT1A | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759930801, COSV64745240, COSV64746279; called by muse, mutect2, varscan2
- MC1R | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.72); catalogued as rs749525002, CM062835, COSV59626039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCF2L | c.3019A>G p.T1007A (on ENST00000375608; = p.T975A on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56179413; called by muse, mutect2, varscan2
- MCF2L2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs773032244, COSV61055281; called by muse, mutect2, varscan2
- MCM7 | c.994T>G p.F332V | Missense Mutation (SNP) | VAF 102/542 reads (19%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.692); catalogued as COSV57997424; called by muse, mutect2, varscan2
- MCPH1 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370011131, COSV60913710; called by muse, mutect2, varscan2
- MED11 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53411855; called by muse, varscan2
- MED12L | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56386096; called by muse, mutect2, varscan2
- MED30 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV52067220; called by muse, mutect2
- MEIS3 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs748298649, COSV58984168; called by muse, mutect2, varscan2
- METTL27 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV52896461; called by muse, mutect2
- MFSD3 | c.1048G>C p.A350P | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV56741900; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | catalogued as rs769987847; called by mutect2, varscan2
- MGMT | c.211G>A p.A71T (on ENST00000306010; = p.A40T on NM_002412.5) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.216); catalogued as COSV60030634; called by muse, mutect2, varscan2
- MIA3 | c.4509A>C p.Q1503H | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV60514970; called by muse, mutect2, varscan2
- MIB2 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.385); catalogued as rs776261867, COSV61756410; called by muse, mutect2, varscan2
- MKI67 | c.6995C>T p.T2332M | Missense Mutation (SNP) | VAF 292/831 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs182397079, COSV64073813; called by muse, mutect2, varscan2
- MOGS | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV51968580; called by muse, mutect2, varscan2
- MRC2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.033); catalogued as COSV57641735; called by muse, mutect2, varscan2
- MROH2B | c.2590C>T p.R864* | Nonsense Mutation (SNP) | VAF 53/128 reads (41%) | catalogued as rs770970800, COSV68186527; called by muse, mutect2, varscan2
- MROH5 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs916797497, COSV71301285; called by muse, mutect2, varscan2
- MRTFA | c.1878G>A p.M626I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV62934686; called by muse, mutect2, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | catalogued as rs34028511; called by mutect2, pindel, varscan2
- MSL2 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV53867089; called by muse, mutect2, varscan2
- MTHFD1 | c.80T>C p.L27S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs1201820242, COSV53701857; called by muse, mutect2, varscan2
- MTUS2 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs747494603, COSV70916004; called by muse, mutect2, varscan2
- MTUS2 | c.3781C>T p.L1261F (on ENST00000612955 / NM_001366650.1; = p.L240F on NM_015233.6) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV66422074, COSV66422296; called by muse, mutect2, varscan2
- MUC16 | c.36920A>G p.D12307G | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV67478140; called by muse, mutect2, varscan2
- MUC16 | c.28289del p.N9430Tfs*13 | Frame Shift Del (DEL) | VAF 48/193 reads (25%) | catalogued as rs774904775; called by mutect2, pindel, varscan2
- MUC16 | c.18502G>T p.G6168C | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV67449722, COSV67478144; called by muse, mutect2, varscan2
- MUC16 | c.10538C>T p.A3513V | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.025); catalogued as rs1331116243, COSV67478148; called by muse, mutect2, varscan2
- MUC17 | c.5899C>T p.P1967S | Missense Mutation (SNP) | VAF 284/639 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.732); catalogued as rs568723888, COSV60295022; called by muse, mutect2, varscan2
- MVK | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374686559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPH | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55143197; called by muse, mutect2, varscan2
- MYH13 | c.3604G>T p.D1202Y | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52827465; called by muse, mutect2, varscan2
- MYH2 | c.4516C>T p.R1506* | Nonsense Mutation (SNP) | VAF 82/261 reads (31%) | catalogued as COSV55430702; called by muse, mutect2, varscan2
- MYO18B | c.7490A>G p.E2497G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV59140514; called by muse, mutect2, varscan2
- MYO1B | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200675888, COSV58430438; called by muse, mutect2, varscan2
- MYO1C | c.1694T>C p.L565P (on ENST00000648651 / NM_001080779.2; = p.L530P on NM_033375.5) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62999946; called by muse, mutect2, varscan2
- MYO5A | c.4922T>C p.V1641A | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV62562189; called by muse, mutect2, varscan2
- MYO7B | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67349215; called by muse, mutect2, varscan2
- MYO9B | c.1903C>T p.H635Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68280857; called by muse, mutect2, varscan2
- MYPN | c.3364C>A p.L1122M | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62735615; called by muse, mutect2, varscan2
- MZF1 | c.1250G>T p.C417F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53042216; called by muse, mutect2, varscan2
- NALCN | c.4483C>T p.R1495W | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485549287, COSV51921358; called by muse, mutect2, varscan2
- NALCN | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs758366704, COSV51915323; called by muse, mutect2, varscan2
- NAV2 | c.5716C>T p.Q1906* (on ENST00000396087 / NM_001244963.2; = p.Q1847* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV60661628; called by muse, mutect2, varscan2
- NCAPG | c.2260G>A p.V754M | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs111401034; called by muse, mutect2, varscan2
- NCKAP5L | c.3451C>T p.R1151W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759471693, COSV60131058; called by muse, mutect2, varscan2
- NCOA1 | c.2240A>G p.Q747R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV56048355; called by muse, mutect2, varscan2
- NCOA1 | c.3879_3881del p.N1294del | In Frame Del (DEL) | VAF 13/63 reads (21%) | catalogued as rs773887238; called by pindel, varscan2
- NDE1 | c.726del p.T243Pfs*28 (on ENST00000577101; = p.T243Pfs*115 on NM_017668.3) | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs1567656871; called by mutect2, pindel, varscan2
- NDRG1 | c.66C>A p.T22= | Splice Region (SNP) | VAF 20/94 reads (21%) | catalogued as COSV60484918; called by muse, mutect2, varscan2
- NDST3 | c.2303A>G p.D768G | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56623156; called by muse, mutect2, varscan2
- NDUFS1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181556411, COSV51911186; called by muse, mutect2
- NEB | c.10811C>T p.T3604I | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs766876980, COSV51433653; called by muse, mutect2, varscan2
- NEB | c.5615del p.P1872Rfs*25 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | catalogued as COSV51121097; called by mutect2, pindel, varscan2
- NECAB2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201570211; called by muse, mutect2, varscan2
- NECAP1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776291688, COSV60249934; called by muse, mutect2, varscan2
- NEK8 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs779175681, COSV52046183; called by muse, mutect2, varscan2
- NEPRO | c.1645T>C p.S549P | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs150027810; called by muse, mutect2, varscan2
- NEU2 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV52093309; called by muse, mutect2, varscan2
- NFAT5 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1194969642, COSV63029509; called by muse, mutect2, varscan2
- NFATC4 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.739); catalogued as COSV51606672; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs1171412241, CD054388; called by mutect2, pindel, varscan2
- NIBAN3 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as COSV56311281; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as COSV53499514; called by mutect2, varscan2
- NIPBL | c.3716A>C p.N1239T | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56957457; called by muse, mutect2
- NLRC4 | c.2324T>C p.M775T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV61593662; called by muse, mutect2, varscan2
- NLRP6 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100381045; called by muse, mutect2, varscan2
- NMI | c.553C>G p.R185G | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV54638586; called by muse, mutect2, varscan2
- NPAS3 | c.1322C>T p.T441I (on ENST00000356141 / NM_001164749.2; = p.T409I on NM_022123.3) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1566552281, COSV60845111; called by muse, mutect2, varscan2
- NPLOC4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286794905, COSV58617479; called by muse, mutect2, varscan2
- NRAP | c.5180C>G p.A1727G (on ENST00000359988 / NM_001322945.2; = p.A1692G on NM_006175.4) | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.047); catalogued as COSV63492190; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 38/162 reads (23%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN1 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60508639; called by muse, mutect2, varscan2
- NSF | c.2115A>G p.I705M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV56575580; called by muse, mutect2, varscan2
- NUCB2 | c.797T>C p.L266S | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60376030; called by muse, mutect2, varscan2
- NUCB2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs771755760, COSV60376040; called by muse, mutect2
- NUDT2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV60678731; called by muse, varscan2
- NUP62 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs142980354; called by muse, mutect2, varscan2
- OAF | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61109554; called by muse, mutect2, varscan2
- OBSCN | c.18344G>A p.R6115Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs564703455, COSV52794869; called by muse, mutect2, varscan2
- ODF2 | c.1607T>C p.V536A (on ENST00000434106 / NM_153433.2; = p.V512A on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV63547970; called by muse, mutect2, varscan2
- OLA1 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52971850; called by muse, mutect2, varscan2
- OLFM2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs751696026, COSV53431934; called by muse, mutect2, varscan2
- OR10J5 | c.263A>G p.H88R | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58386828; called by muse, mutect2, varscan2
- OR10T2 | c.314del p.F105Sfs*14 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | catalogued as rs1408969842; called by mutect2, pindel, varscan2
- OR2A4 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs763408926; called by mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR52E2 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV58612967, COSV58613850; called by muse, mutect2, varscan2
- OR52I1 | c.568A>G p.R190G | Missense Mutation (SNP) | VAF 90/357 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV56169088; called by muse, mutect2, varscan2
- OR52K1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1280602964, COSV56904144; called by muse, mutect2
- OR5J2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs138599396; called by muse, mutect2, varscan2
- OR5T2 | c.889A>G p.M297V | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV57590015; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 78/248 reads (31%) | catalogued as rs746200712; called by mutect2, varscan2
- OR8B4 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62070112; called by muse, mutect2, varscan2
- OR8H3 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 268/941 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV57909959; called by muse, mutect2, varscan2
- OR8I2 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV56168910; called by muse, mutect2, varscan2
- ORC1 | c.1483C>T p.L495= | Splice Region (SNP) | VAF 64/233 reads (27%) | catalogued as COSV65364450; called by muse, mutect2, varscan2
- OSGIN2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 70/348 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs533674331, COSV52408402; called by muse, mutect2, varscan2
- OSGIN2 | c.1217T>G p.L406R | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV52409644; called by muse, mutect2
- P2RY1 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59309874; called by muse, mutect2, varscan2
- P2RY12 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56386086; called by muse, mutect2, varscan2
- P2RY8 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1437744214, COSV67177790; called by muse, mutect2, varscan2
- PACRGL | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs183601092; called by muse, mutect2, varscan2
- PAN2 | c.2201T>C p.I734T (on ENST00000425394 / NM_001127460.3; = p.I730T on NM_014871.5) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV57754644; called by muse, mutect2, varscan2
- PAPPA2 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs762450904, COSV62781547; called by muse, mutect2, varscan2
- PARD3B | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs199890873, COSV62507799; called by muse, mutect2, varscan2
- PARP10 | c.674-2A>T p.X225_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV57298864; called by muse, varscan2
- PARP10 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs782082984, COSV57298871; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs758945932; called by mutect2, varscan2
- PAX6 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs758400541, COSV53794495; called by muse, mutect2, varscan2
- PBRM1 | c.182A>C p.K61T | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56287216; called by muse, mutect2, varscan2
- PCCA | c.1778C>T p.T593I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV66194708; called by muse, mutect2, varscan2
- PCDHA1 | c.2180C>A p.P727H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV65375416; called by muse, mutect2, varscan2
- PCDHA3 | c.1652T>G p.L551R | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV63543532; called by muse, mutect2, varscan2
- PCDHA7 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV65345031; called by muse, mutect2, varscan2
- PCDHA9 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as COSV65329039; called by muse, mutect2, varscan2
- PCDHB6 | c.1610C>G p.P537R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV50706023, COSV50706653; called by muse, varscan2
- PCDHB9 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV53381158; called by muse, mutect2, varscan2
- PCDHGA12 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.158); catalogued as COSV52758003; called by muse, mutect2, varscan2
- PCED1B | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770009860, COSV71395439; called by muse, mutect2, varscan2
- PCNX3 | c.3784G>A p.A1262T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63138572; called by muse, mutect2, varscan2
- PCSK5 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65084686; called by muse, mutect2, varscan2
- PDZD2 | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56864180; called by muse, mutect2, varscan2
- PDZD2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1352596877, COSV56854244, COSV56868635; called by muse, mutect2
- PDZD4 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.1); catalogued as rs1194559953, COSV51247168; called by muse, mutect2, varscan2
- PEF1 | c.764A>C p.E255A | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV65483946; called by muse, mutect2, varscan2
- PEG10 | c.833G>A p.R278H (on ENST00000482108 / NM_001040152.2; = p.R312H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV71788765; called by muse, varscan2
- PGM3 | c.1179A>T p.Q393H | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52284829; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF21A | c.467T>A p.I156N | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV57656573; called by muse, mutect2, varscan2
- PHLDA2 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV56540820; called by muse, mutect2, varscan2
- PI4K2A | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs371681790, COSV101034308; called by muse, mutect2, varscan2
- PIDD1 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427628817, COSV57194072; called by muse, mutect2, varscan2
- PIGR | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 43/167 reads (26%) | catalogued as COSV62904370; called by muse, mutect2, varscan2
- PIK3C2A | c.4663A>G p.T1555A | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV56404663; called by muse, mutect2, varscan2
- PIK3R6 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.993); catalogued as COSV61004206; called by muse, mutect2, varscan2
- PKHD1 | c.3242G>A p.R1081H | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs201123815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs564240823, COSV61859047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKP1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs188436125, COSV55819570; called by muse, varscan2
- PLAA | c.1324A>G p.M442V | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs751605997, COSV68305210; called by muse, mutect2, varscan2
- PLCG1 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs141297485; called by muse, mutect2, varscan2
- PLCXD3 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 33/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60612432; called by muse, mutect2, varscan2
- PLEKHA6 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs545557896, COSV55334926, COSV55336251; called by muse, mutect2, varscan2
- PLEKHG3 | c.980G>A p.R327Q (on ENST00000394691; = p.R383Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs138713446; called by muse, mutect2, varscan2
- PLEKHG4 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV64613355; called by muse, mutect2, varscan2
- PLXNA2 | c.3674C>T p.S1225L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs140111660, COSV65442442; called by muse, mutect2
- PLXNA4 | c.5333T>C p.F1778S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58141391; called by muse, mutect2, varscan2
- PLXND1 | c.3600+1G>A p.X1200_splice | Splice Site (SNP) | VAF 56/265 reads (21%) | catalogued as rs751249482, COSV60716040; called by muse, mutect2, varscan2
- PNO1 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54562118; called by muse, mutect2, varscan2
- POLD1 | c.2414G>A p.S805N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54531187; called by muse, mutect2, varscan2
- POLQ | c.5491G>A p.A1831T | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772328819, COSV51756276; called by muse, mutect2, varscan2
- POLRMT | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777128308, COSV52116719; called by muse, mutect2, varscan2
- POU4F2 | c.1097T>G p.I366S | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV55585552; called by muse, mutect2, varscan2
- PPFIA3 | c.2957A>G p.H986R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53257431; called by muse, mutect2, varscan2
- PPM1E | c.2044A>G p.R682G | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV57576671; called by muse, mutect2, varscan2
- PPM1F | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 27/136 reads (20%) | catalogued as rs759818451, COSV54285237; called by muse, mutect2, varscan2
- PPP2R5E | c.1202+1G>A p.X401_splice | Splice Site (SNP) | VAF 51/194 reads (26%) | catalogued as COSV61742326; called by muse, mutect2, varscan2
- PPRC1 | c.2111del p.G704Vfs*30 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | catalogued as COSV99531679; called by mutect2, pindel, varscan2
- PRG4 | c.2255C>T p.T752I | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV63355963; called by muse, varscan2
- PRKAB1 | c.80dup p.T28Hfs*39 | Frame Shift Ins (INS) | VAF 6/37 reads (16%) | catalogued as rs765766033; called by mutect2, pindel, varscan2
- PRKAR2B | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1379361464, COSV55922685, COSV55926020; called by muse, mutect2, varscan2
- PRKG2 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV52327523; called by muse, mutect2, varscan2
- PROM1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71699647; called by muse, mutect2, varscan2
- PRPSAP1 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as rs766959868, COSV61210281, COSV61211808; called by muse, mutect2, varscan2
- PRUNE1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54958955; called by muse, mutect2, varscan2
- PSMB2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.057); catalogued as rs371637537; called by muse, mutect2, varscan2
- PSMD3 | c.1584T>A p.D528E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV52858574; called by muse, mutect2
- PTPN7 | c.21del p.R8Afs*7 (on ENST00000495688; = p.R47Afs*7 on NM_002832.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as rs754051725; called by mutect2, pindel, varscan2
- PTPN9 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs114183309, COSV100144262, COSV60723430; called by muse, mutect2, varscan2
- PYROXD2 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 35/205 reads (17%) | catalogued as rs146494121, COSV65330630; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 34/128 reads (27%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB12 | c.620del p.K207Rfs*7 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs1187846263; called by mutect2, pindel
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAPGEF2 | c.3259del p.I1087Ffs*98 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as rs760669443; called by mutect2, pindel*, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 28/139 reads (20%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RASGRF2 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1219870856, COSV54133107; called by muse, mutect2
- RASSF2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs754308859, COSV65082426; called by muse, mutect2, varscan2
- RBFA | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100080230; called by muse, mutect2, varscan2
- RBL1 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as COSV60331144; called by muse, mutect2, varscan2
- RBM7 | c.720G>T p.R240S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV64955795; called by muse, mutect2, varscan2
- RBMS3 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs763252410, COSV56155024; called by muse, mutect2, varscan2
- RBP5 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV56952342; called by muse, mutect2, varscan2
- RECQL5 | c.1292G>A p.C431Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58642986; called by muse, mutect2, varscan2
- RGS1 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.248); catalogued as COSV66505821; called by muse, mutect2, varscan2
- RGS22 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774013023, COSV62664363; called by muse, mutect2, varscan2
- RGS22 | c.211dup p.I71Nfs*13 | Frame Shift Ins (INS) | VAF 40/176 reads (23%) | catalogued as rs1344877867; called by mutect2, varscan2
- RHOBTB2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); catalogued as rs775527995, COSV52570351, COSV52572102; called by muse, mutect2, varscan2
- RHOJ | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV57459743; called by muse, mutect2, varscan2
- RNF113B | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57435472; called by muse, mutect2, varscan2
- RNF13 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs200489974; called by muse, mutect2, varscan2
- RNF17 | c.2141A>G p.Y714C | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55044821; called by muse, mutect2, varscan2
- RNF214 | c.1544G>A p.G515D | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV56119810; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV68457287, COSV68458942; called by muse, mutect2, varscan2
- RNF43 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV68459026; called by muse, mutect2, varscan2
- RNF5 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as rs750217083, COSV61248139; called by muse, mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 80/262 reads (31%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROCK1 | c.2304A>C p.E768D | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV67697108; called by muse, mutect2, varscan2
- RP1 | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1195531660, COSV55120896; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KL1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs372803014; called by muse, mutect2, varscan2
- RSPH1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1273361305, COSV52320293; called by muse, mutect2, varscan2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 48/192 reads (25%) | catalogued as rs771992011; called by mutect2, varscan2
- RTN2 | c.178dup p.R60Pfs*11 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs763387041; called by mutect2, pindel, varscan2
- RXFP3 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV57504801; called by muse, mutect2, varscan2
- SAMD4B | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766851887, COSV58752328; called by muse, mutect2, varscan2
- SCN2B | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs768191108, COSV54051250; called by muse, mutect2, varscan2
- SCN3A | c.2498G>A p.S833N | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV51815795; called by muse, mutect2, varscan2
- SCNN1B | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as COSV100225738; called by muse, mutect2, varscan2
- SCNN1D | c.1171-1G>T p.X391_splice (on ENST00000338555; = p.X555_splice on NM_001130413.4) | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV57642738; called by muse, mutect2, varscan2
- SCYL1 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs370521030; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SELP | c.2420G>T p.C807F | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55254634; called by muse, mutect2, varscan2
- SELPLG | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771908051, COSV57313686; called by muse, mutect2, varscan2
- SEMA3G | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV51596839; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as rs750651342; called by mutect2, varscan2
- SENP3 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1267852896, COSV99549003; called by muse, mutect2, varscan2
- SERPINA4 | c.903G>A p.W301* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as rs1163842908, COSV54070758; called by muse, mutect2, varscan2
- SERPING1 | c.564C>A p.N188K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.192); catalogued as COSV53543418; called by muse, mutect2, varscan2
- SESTD1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58931864; called by muse, mutect2, varscan2
- SETDB1 | c.2849del p.P950Qfs*16 | Frame Shift Del (DEL) | VAF 58/204 reads (28%) | catalogued as rs1220025296; called by mutect2, pindel, varscan2
- SFXN5 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as rs770902510, COSV55588310; called by muse, mutect2, varscan2
- SGIP1 | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as COSV52773288; called by muse, mutect2, varscan2
- SGO1 | c.1564dup p.R522Kfs*29 (on ENST00000263753 / NM_001012410.5; = p.R253Kfs*29 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 17/76 reads (22%) | catalogued as rs772386209; called by mutect2, varscan2
- SH2B1 | c.1771C>T p.H591Y | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59464798; called by muse, mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SIN3B | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.623); catalogued as COSV56134569; called by muse, mutect2, varscan2
- SIPA1L3 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99729181; called by muse, mutect2, varscan2
- SLC11A1 | c.597del p.F199Lfs*5 | Frame Shift Del (DEL) | VAF 187/735 reads (25%) | catalogued as rs1362974823; called by mutect2, pindel, varscan2
- SLC15A2 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV55199055; called by muse, mutect2, varscan2
- SLC16A10 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs760684404, COSV64354854; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 25/98 reads (26%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC17A6 | c.776T>G p.F259C | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV54138397; called by muse, mutect2, varscan2
- SLC19A2 | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); catalogued as COSV52548135; called by muse, mutect2, varscan2
- SLC19A3 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.585); catalogued as COSV51453823; called by muse, mutect2, varscan2
- SLC22A13 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs763123804, COSV61291512; called by muse, mutect2, varscan2
- SLC25A31 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs752061699, COSV55420111; called by muse, mutect2, varscan2
- SLC2A12 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.23); catalogued as rs151202816; called by muse, mutect2, varscan2
- SLC2A9 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs367643471; called by muse, mutect2, varscan2
- SLC36A2 | c.203T>G p.M68R | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV58864030; called by muse, mutect2, varscan2
- SLC45A1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.185); catalogued as rs535344724, COSV57093330; called by muse, mutect2, varscan2
- SLC47A1 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1321921564, COSV54502429; called by muse, mutect2, varscan2
- SLC4A3 | c.856A>G p.K286E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV56095526; called by muse, mutect2, varscan2
- SLC4A5 | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234158492, COSV61030051; called by muse, mutect2, varscan2
- SLC5A9 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs1037027712, COSV52584494; called by muse, mutect2, varscan2
- SLC66A2 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs759347267, COSV60843893; called by muse, mutect2, varscan2
- SLC6A11 | c.1771A>G p.S591G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV54393084; called by muse, mutect2, varscan2
- SLC9A5 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as rs1163401561, COSV55363269; called by muse, mutect2, varscan2
- SLC9C2 | c.597dup p.G200Wfs*14 | Frame Shift Ins (INS) | VAF 37/167 reads (22%) | catalogued as rs760633653; called by mutect2, varscan2
- SLCO4C1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs766101499, COSV60517653; called by muse, mutect2, varscan2
- SLFN5 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs139273106; called by muse, mutect2, varscan2
- SMC4 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58449696; called by muse, mutect2
- SNAI3 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776627093, COSV60002275; called by muse, mutect2, varscan2
- SNX25 | c.1716dup p.V573Sfs*7 | Frame Shift Ins (INS) | VAF 36/132 reads (27%) | catalogued as rs780499770; called by mutect2, varscan2
- SOGA3 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs763744908, COSV64107446; called by muse, mutect2, varscan2
- SORBS1 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs542089666, COSV53360694; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 37/212 reads (17%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SPAG8 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs1215929705, COSV52414694; called by muse, mutect2, varscan2
- SPARCL1 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV56804989; called by muse, mutect2, varscan2
- SPDL1 | c.548_550del p.E183del | In Frame Del (DEL) | VAF 28/75 reads (37%) | catalogued as rs1462822633; called by pindel, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs750890082; called by mutect2, varscan2
- SPEG | c.6470G>T p.G2157V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV56673943; called by muse, mutect2, varscan2
- SPEN | c.10208G>A p.R3403H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.022); catalogued as rs549789481, COSV65269552; called by muse, mutect2, varscan2
- SRCAP | c.3843C>A p.S1281R | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV52676212; called by muse, mutect2, varscan2
- SRD5A1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs545726471, COSV57014616; called by muse, mutect2, varscan2
- SRGAP3 | c.3079C>A p.R1027S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.145); catalogued as COSV64537736; called by muse, mutect2
- SRPK2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250941626, COSV61960646, COSV61962399; called by muse, mutect2, varscan2
- SRPX | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59437691, COSV59439841; called by muse, mutect2, varscan2
- ST18 | c.2686A>G p.N896D | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs773360476, COSV52500337; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAB1 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs746483398, COSV58739708; called by muse, mutect2, varscan2
- STAP1 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1253369617, COSV55328783; called by muse, mutect2, varscan2
- STK10 | c.1705C>A p.L569I | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51570491; called by muse, mutect2
- STK32A | c.26C>G p.P9R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV60420246; called by muse, mutect2, varscan2
- STOML2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377638110, COSV58927330; called by muse, varscan2
- STOX1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374535579; called by muse, mutect2, varscan2
- STPG2 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761562487, COSV99759829; called by mutect2, varscan2
- STXBP1 | c.*5del | Frame Shift Del (DEL) | VAF 32/120 reads (27%) | catalogued as rs752807764, COSV58854018; called by mutect2, pindel
- SUPT6H | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs746218200, COSV58929100; called by muse, mutect2, varscan2
- SUPT6H | c.370del p.M124Cfs*70 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs1372943034; called by mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYNE1 | c.26047T>C p.S8683P (on ENST00000367255 / NM_182961.4; = p.S8635P on NM_033071.3) | Missense Mutation (SNP) | VAF 14/255 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as COSV55029645; called by muse, mutect2
- SYNE1 | c.5872G>T p.E1958* (on ENST00000367255 / NM_182961.4; = p.E1965* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 106/388 reads (27%) | catalogued as COSV55029678; called by muse, mutect2, varscan2
- SYNE1 | c.2179G>A p.A727T (on ENST00000367255 / NM_182961.4; = p.A734T on NM_033071.3) | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.156); catalogued as COSV55029711; called by muse, mutect2, varscan2
- SYNJ2 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368394869; called by muse, mutect2, varscan2
- SYNPO | c.1978G>A p.V660M (on ENST00000394243 / NM_001166208.2; = p.V416M on NM_007286.6) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs200584473, COSV56941161; called by muse, mutect2, varscan2
- SYT10 | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57342463; called by muse, mutect2, varscan2
- TBCB | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs773011907, COSV55692957; called by muse, mutect2, varscan2
- TBKBP1 | c.1786G>A p.G596R | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442310303, COSV64653380; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 53/202 reads (26%) | catalogued as rs758822980; called by mutect2, varscan2
- TCHH | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); catalogued as COSV64276110; called by muse, mutect2, varscan2
- TEP1 | c.5566del p.V1856Lfs*45 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs746695887; called by mutect2, pindel, varscan2
- TESK1 | c.1732T>G p.F578V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV52411693; called by muse, mutect2, varscan2
- TG | c.7679C>T p.A2560V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55084244; called by muse, varscan2
- THNSL1 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64479560; called by muse, mutect2, varscan2
- THSD4 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 105/335 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs189738200, COSV55959709; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as COSV50235787; called by mutect2, varscan2
- TJP3 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53663984; called by muse, mutect2, varscan2
- TLR10 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs776224049, COSV58301227; called by muse, mutect2, varscan2
- TMEM198 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs765008645, COSV54724053; called by muse, varscan2
- TMEM63A | c.1479G>A p.W493* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV64763554; called by muse, mutect2, varscan2
- TMEM67 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV60039657; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs781830688; called by mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 51/101 reads (50%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNRC6A | c.2989C>T p.R997C | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766143258, COSV59367108; called by muse, mutect2, varscan2
- TNS1 | c.31T>C p.C11R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.701); catalogued as COSV50722851; called by muse, mutect2, varscan2
- TNS3 | c.1772G>T p.R591L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV60794356; called by muse, mutect2, varscan2
- TP53TG5 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs369818892; called by muse, mutect2, varscan2
- TPO | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as CM138369, COSV61105353; called by muse, mutect2, varscan2
- TRAF6 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 87/345 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV61922995; called by muse, mutect2, varscan2
- TRDN | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100521697, COSV62126156; called by muse, mutect2, varscan2
- TRERF1 | c.1771A>G p.K591E | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV61674523; called by muse, mutect2, varscan2
- TRH | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.809); catalogued as rs1191206604, COSV57014864; called by muse, mutect2, varscan2
- TRHDE | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53853279; called by muse, mutect2
- TRIM14 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV52964508; called by muse, mutect2
- TRIM3 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV61984622; called by muse, mutect2, varscan2
- TRIM9 | c.176A>C p.D59A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV53620462; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as rs752676391; called by mutect2, varscan2
- TRIOBP | c.6703C>T p.Q2235* (on ENST00000644935 / NM_001039141.3; = p.Q522* on NM_007032.5) | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60380474; called by muse, mutect2
- TRIR | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.785); catalogued as COSV54407255; called by muse, mutect2
- TRPM3 | c.3719A>G p.N1240S (on ENST00000357533 / NM_001366142.2; = p.N1095S on NM_020952.6) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV62589639; called by muse, mutect2, varscan2
- TRPM7 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758746706, COSV57918964; called by muse, mutect2, varscan2
- TSPAN11 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs140179345; called by muse, mutect2, varscan2
- TTN | c.95242C>A p.P31748T (on ENST00000591111; = p.P24324T on NM_003319.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | PolyPhen benign (0.43); catalogued as COSV100600666; called by muse, mutect2
- TTN | c.35685del p.K11895Nfs*2 (on ENST00000591111; = p.K4471Nfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | catalogued as rs1284446305; called by mutect2, varscan2
- TTN | c.23203A>G p.T7735A (on ENST00000591111; = p.T6808A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/126 reads (29%) | PolyPhen benign (0.003); catalogued as COSV60177082; called by muse, mutect2, varscan2
- TUBA3D | c.1192A>G p.M398V | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV58312477; called by muse, varscan2
- TUBB6 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV52315839; called by muse, mutect2, varscan2
- TXNRD2 | c.662+1G>A p.X221_splice | Splice Site (SNP) | VAF 24/92 reads (26%) | catalogued as rs1317400468, COSV57634250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2U | c.108G>T p.W36C | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64281244, COSV64281638; called by muse, mutect2, varscan2
- UBE4B | c.3419A>C p.N1140T (on ENST00000343090 / NM_001105562.3; = p.N1011T on NM_006048.5) | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV53536064; called by muse, mutect2, varscan2
- UBN2 | c.3591G>T p.Q1197H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56032918; called by mutect2, varscan2
556 further variants in this file (249 protein-altering or splice-affecting, 278 silent, 29 other) are not listed here.
